Somatic mutation profile of tumor specimen TCGA-B8-4620-01A (aliquot TCGA-B8-4620-01A-01D-1553-08) from TCGA case TCGA-B8-4620, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 70.6 years (25,786 days).
Specimen TCGA-B8-4620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea27563d-d5ed-4115-b234-e49542727e32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-4620-10A (Blood Derived Normal), aliquot TCGA-B8-4620-10A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be69e44d-63c5-4516-a2ca-bc9ddfdb5a2a

The open-access MAF lists 47 somatic variants for this specimen: 41 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Frame Shift Del 7, Silent 4, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.7111G>A p.V2371I | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); catalogued as COSV54955935; called by muse, mutect2, varscan2
- AKT1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); catalogued as COSV62573390; called by muse, mutect2, varscan2
- ANAPC1 | c.5363del p.P1788Lfs*10 | Frame Shift Del (DEL) | VAF 33/235 reads (14%) | catalogued as COSV61977905; called by mutect2, pindel, varscan2
- ASH2L | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51699587; called by muse, mutect2, varscan2
- ASTL | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); catalogued as rs773350568, COSV100668453; called by muse, varscan2
- ATP1A2 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs779812635, COSV63402362, COSV63403685; called by muse, mutect2, varscan2
- B2M | c.150del p.H51Ifs*10 | Frame Shift Del (DEL) | VAF 49/205 reads (24%) | catalogued as COSV62563554; called by pindel, varscan2
- CD55 | c.192A>C p.K64N | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV58576969; called by muse, mutect2, varscan2
- CFHR2 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs754703889, COSV66381095; called by muse, mutect2, varscan2
- CLCN7 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.794); catalogued as COSV51970535, COSV99247227; called by muse, mutect2, varscan2
- COBL | c.2704G>C p.V902L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV54345818; called by muse, mutect2, varscan2
- DLK2 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV55087786; called by muse, mutect2, varscan2
- DPYD | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV64597636, COSV64614422; called by muse, mutect2, varscan2
- FAM124A | c.544A>T p.N182Y (on ENST00000322475 / NM_001242312.2; = p.N218Y on NM_145019.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs538055450, COSV54476633; called by muse, mutect2, varscan2
- FANCB | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV60759897; called by muse, mutect2, varscan2
- FLG | c.8176G>A p.G2726S | Missense Mutation (SNP) | VAF 87/332 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV100910283; called by muse, varscan2
- FLG2 | c.6263G>C p.G2088A | Missense Mutation (SNP) | VAF 336/694 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); catalogued as rs762578859, COSV66168681; called by muse, mutect2, varscan2
- H3C13 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as rs1197534607; called by muse, mutect2
- IFITM2 | c.223A>C p.I75L | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as COSV67714633; called by muse, mutect2, varscan2
- IYD | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as COSV57601120; called by muse, mutect2, varscan2
- KIR3DL1 | c.1280del p.L427Cfs*51 | Frame Shift Del (DEL) | VAF 86/413 reads (21%) | catalogued as COSV58489912, COSV58491961; called by mutect2, pindel, varscan2
- MITF | c.491G>A p.G164D (on ENST00000448226 / NM_006722.3; = p.G58D on NM_000248.4) | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV58831478; called by muse, mutect2, varscan2
- MUC16 | c.16789G>A p.V5597M | Missense Mutation (SNP) | VAF 73/136 reads (54%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.025); catalogued as rs751532991, COSV67465644, COSV67474328; called by muse, mutect2, varscan2
- NEGR1 | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs776574702, COSV100747038, COSV63248672; called by muse, mutect2
- NHSL2 | c.2008A>G p.I670V (on ENST00000510661; = p.I1036V on NM_001013627.2) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as rs1292990423, COSV65452723, COSV65453419; called by muse, mutect2, varscan2
- SACS | c.3957G>C p.K1319N | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV66539857; called by muse, mutect2, varscan2
- SACS | c.3956A>C p.K1319T | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.88); catalogued as COSV66539876; called by muse, mutect2, varscan2
- SERPINI1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55510749; called by muse, mutect2, varscan2
- SGK1 | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV52808398; called by muse, mutect2, varscan2
- STAU2 | c.655C>G p.R219G (on ENST00000524300 / NM_001164380.2; = p.R187G on NM_014393.2) | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV63308147; called by muse, mutect2, varscan2
- STAU2 | c.654G>T p.K218N (on ENST00000524300 / NM_001164380.2; = p.K186N on NM_014393.2) | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63308241, COSV63308680; called by muse, mutect2, varscan2
- SUSD2 | c.476A>C p.E159A | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.039); catalogued as COSV64203885; called by muse, mutect2, varscan2
- TAB3 | c.2089C>T p.H697Y | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55836949; called by muse, mutect2, varscan2
- TDRD6 | c.2746A>C p.K916Q | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV60175698; called by muse, mutect2, varscan2
- TRIM41 | c.557G>C p.C186S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59319096, COSV59319187; called by muse, mutect2, varscan2
- VHL | c.482G>C p.R161P | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM951290, CM961431, COSV104374399, COSV56542648, COSV56545213, COSV56545244; called by muse, mutect2, varscan2
- ADAMTS13 | c.618del p.W206* | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- EPAS1 | c.2537_2538del p.V846Efs*55 | Frame Shift Del (DEL) | VAF 65/197 reads (33%) | called by mutect2, pindel, varscan2
- PBRM1 | c.2500del p.Y834Tfs*21 | Frame Shift Del (DEL) | VAF 64/117 reads (55%) | called by mutect2, pindel, varscan2
- SETD2 | c.5981_5990del p.R1994Nfs*9 | Frame Shift Del (DEL) | VAF 105/199 reads (53%) | called by mutect2, pindel, varscan2
- TGFBRAP1 | c.2029G>T p.G677C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ART1 | c.783C>T p.P261= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as rs139469651; called by muse, mutect2, varscan2
- HACE1 | c.177T>C p.Y59= | Silent (SNP) | VAF 106/303 reads (35%) | catalogued as rs765859242, COSV53502391; called by muse, mutect2, varscan2
- NAP1L3 | c.759A>G p.K253= | Silent (SNP) | VAF 99/343 reads (29%) | catalogued as COSV59075321, COSV59077756; called by muse, mutect2, varscan2
- TNFAIP1 | c.273C>T p.T91= | Silent (SNP) | VAF 52/225 reads (23%) | catalogued as COSV56876651; called by muse, mutect2, varscan2
- C1orf122 | c.*22T>C | 3'UTR (SNP) | VAF 78/154 reads (51%) | catalogued as COSV100888552; called by muse, mutect2, varscan2
- UBTFL2 | n.699C>T | RNA (SNP) | VAF 27/164 reads (16%) | called by mutect2, varscan2
